Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4363, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4363-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Body, posterior wall. Tumor configuration: Ulcerating. Tumor size: 7 x 7 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file aa988f6c-d3ec-4498-b6d6-0c34fa2536a8 (TCGA-BR-4363.534F62AD-FCA6-4895-98C0-E2C3DA4F9DA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).